Somatic mutation profile of tumor specimen TCGA-L5-A893-01A (aliquot TCGA-L5-A893-01A-11D-A36J-09) from TCGA case TCGA-L5-A893, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 71.6 years (26,143 days).
Specimen TCGA-L5-A893-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51b75264-d5ea-417f-9915-75a88666ee72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A893-11A (Solid Tissue Normal), aliquot TCGA-L5-A893-11A-21D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43ca3520-5a09-4400-9f02-a44fd40af48e

The open-access MAF lists 130 somatic variants for this specimen: 96 protein-altering or splice-affecting, 33 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 33, Nonsense Mutation 5, Frame Shift Ins 2, Frame Shift Del 1, Translation Start Site 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | hotspot (GDC flag); catalogued as rs121913303, CM961229, COSV57297124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722_724dup p.S241dup | In Frame Ins (INS) | VAF 19/46 reads (41%) | hotspot (GDC flag); catalogued as COSV53672138; called by mutect2, pindel, varscan2
- ABCC9 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 20/39 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); catalogued as COSV53972690; called by muse, mutect2, varscan2
- ACAN | c.2940A>C p.E980D | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.995); catalogued as COSV61357253; called by muse, mutect2, varscan2
- ADAM22 | c.2038T>A p.L680M | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV99717234; called by muse, mutect2, varscan2
- ADAMTS10 | c.2131G>A p.V711I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs564996469, COSV54355869; called by muse, mutect2
- AMACR | c.859T>G p.F287V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1166900433; called by muse, mutect2, varscan2
- BMP8B | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as rs1199094278; called by muse, mutect2, varscan2
- BRINP1 | c.435G>T p.M145I | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV56308429; called by muse, mutect2
- CACNA1F | c.3887G>A p.R1296H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782737751, COSV59907176; called by muse, mutect2, varscan2
- CHRM5 | c.1538G>T p.R513L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV101271858; called by muse, mutect2, varscan2
- CPA6 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV52719710, COSV52732409; called by muse, mutect2, varscan2
- CPED1 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV60002733; called by muse, mutect2, varscan2
- CSMD1 | c.4318T>G p.F1440V (on ENST00000520002; = p.F1439V on NM_033225.6) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100142201, COSV59314221; called by muse, mutect2, varscan2
- DRP2 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs201156733, COSV65811862; called by muse, mutect2, varscan2
- FAM81B | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs374860699; called by muse, mutect2, varscan2
- GALNTL6 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1011629190, COSV72491025, COSV72493992; called by muse, mutect2, varscan2
- GHRL | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs540101934, COSV99814055; called by muse, mutect2, varscan2
- KDM3B | c.4379G>A p.R1460Q | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.685); catalogued as rs529065296; called by muse, mutect2, varscan2
- KMT2E | c.3902C>G p.S1301C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1342250723; called by muse, mutect2, varscan2
- MAPK10 | c.1064T>G p.L355R (on ENST00000359221 / NM_001351625.2; = p.L393R on NM_002753.5) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV60376869; called by muse, mutect2, varscan2
- MARK3 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as rs1157387862; called by muse, mutect2, varscan2
- MARVELD2 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs533462435, COSV104394888; called by muse, mutect2, varscan2
- MIER2 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs140470504, COSV104393194; called by mutect2, varscan2
- MYO5A | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1366384294, COSV62563796, COSV62563960; called by muse, mutect2, varscan2
- NEXMIF | c.3338A>G p.K1113R | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs1569335122; called by muse, mutect2, varscan2
- PRKAG2 | c.1388T>A p.V463E | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55236650; called by muse, mutect2, varscan2
- RASGRF1 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69181834; called by muse, mutect2
- RECQL4 | c.2129G>A p.R710H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs781121286, COSV52879699; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIMS1 | c.4933G>C p.E1645Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV53437811; called by muse, mutect2
- SARDH | c.2204G>A p.W735* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as rs747737814; called by muse, mutect2, varscan2
- SCN9A | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.172); catalogued as rs367556839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIK3 | c.1688G>A p.R563Q (on ENST00000445177 / NM_001366686.2; = p.R569Q on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1479592023, COSV99408696; called by muse, mutect2, varscan2
- SLC45A4 | c.1454G>A p.S485N (on ENST00000517878 / NM_001286646.2; = p.S434N on NM_001080431.2) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV50141622; called by muse, mutect2, varscan2
- SSU72P8 | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1562905775; called by muse, mutect2, varscan2
- TBX5 | c.1161C>A p.S387R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.057); catalogued as rs753688559; called by muse, mutect2, varscan2
- TBX5 | c.954C>A p.S318R | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV59859965; called by muse, mutect2, varscan2
- USH2A | c.3463A>C p.S1155R | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as rs766609270, COSV56372284; called by muse, mutect2, varscan2
- VASH1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1269939707; called by muse, mutect2
- XIRP2 | c.2040A>C p.E680D (on ENST00000628543; = p.E855D on NM_152381.6) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99737663; called by muse, mutect2, varscan2
- YES1 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs750831029, COSV58847713, COSV58853179; called by muse, mutect2, varscan2
- YIPF2 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs780543027; called by muse, mutect2, varscan2
- ZNF790 | c.266C>A p.P89Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV63213383; called by muse, mutect2, varscan2
- ZNF804B | c.165T>G p.F55L | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254569524; called by muse, mutect2, varscan2
- ZNRF4 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753018102, COSV55773885; called by muse, mutect2, varscan2
- AKAP4 | c.2181A>C p.Q727H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1684C>T p.H562Y | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- ATP1A2 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BMP7 | c.553T>G p.F185V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- BMS1 | c.1751C>A p.A584D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- CNTNAP4 | c.3718T>A p.S1240T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- COL5A1 | c.5446A>G p.M1816V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CYLC2 | c.97T>C p.F33L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DCN | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- FAM133A | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- FMO5 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GNAI1 | c.201A>C p.K67N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HDX | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- HFM1 | c.3262C>A p.Q1088K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HUWE1 | c.12965A>G p.K4322R | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2
- IGF2BP3 | c.379T>G p.S127A | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGHG4 | c.506C>A p.T169K | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- IL9R | c.493A>C p.T165P | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ITGB6 | c.1551C>A p.C517* | Nonsense Mutation (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- KCNJ8 | c.163C>G p.R55G | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLRG1 | c.46A>T p.T16S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- MID2 | c.1993C>A p.L665M | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- MPHOSPH8 | c.2399G>A p.G800E | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSN | c.1274C>G p.T425R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, varscan2
- NDUFAF6 | c.358dup p.T120Nfs*8 | Frame Shift Ins (INS) | VAF 23/82 reads (28%) | called by mutect2, varscan2
- NETO1 | c.1367C>A p.T456K | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR10Z1 | c.704A>C p.K235T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OR4K17 | c.900dup p.L301Tfs*9 | Frame Shift Ins (INS) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- PAN3 | c.1339G>T p.D447Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PCDH9 | c.2170G>C p.G724R | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- PDE3A | c.3005A>T p.E1002V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEKHH2 | c.3518G>C p.G1173A | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP1R18 | c.1565G>A p.S522N | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PSMC2 | c.340A>G p.N114D | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- RANBP2 | c.7339del p.S2447Lfs*2 | Frame Shift Del (DEL) | VAF 53/284 reads (19%) | called by mutect2, pindel, varscan2
- RFTN1 | c.746T>G p.L249R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.221); called by muse, mutect2
- RRAGB | c.556T>G p.L186V (on ENST00000262850 / NM_016656.4; = p.L158V on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SERPINA7 | c.477T>A p.F159L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SLC12A1 | c.2032A>C p.K678Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC14A1 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2
- SLCO1B1 | c.165A>G p.I55M | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SMURF1 | c.1753A>C p.K585Q | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- TATDN2 | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TINAGL1 | c.106C>T p.H36Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.069); called by muse, mutect2
- TMTC3 | c.1723A>T p.K575* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.2278G>A p.V760M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TTC3 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.33245C>A p.P11082H (on ENST00000591111; = p.P10155H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/98 reads (15%) | PolyPhen benign (0.159); called by muse, mutect2, varscan2
- USH2A | c.7079C>A p.T2360K | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ZNF454 | c.706A>G p.R236G | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ZNF492 | c.233A>C p.N78T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2
- ABTB2 | c.1299C>T p.Y433= | Silent (SNP) | VAF 32/138 reads (23%) | catalogued as rs916019368; called by muse, mutect2, varscan2
- AGTPBP1 | c.1911G>A p.T637= (on ENST00000357081 / NM_001330701.2; = p.T597= on NM_015239.2) | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs771160356; called by muse, mutect2, varscan2
- ANTKMT | c.513G>A p.V171= | Silent (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- APC | c.6579A>G p.K2193= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs908184283, COSV57331966, COSV57380598; ClinVar: likely benign; called by muse, varscan2
- ARHGAP28 | c.1482A>G p.Q494= (on ENST00000383472 / NM_001366230.1; = p.Q335= on NM_001010000.3) | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- ATP4A | c.2952C>T p.P984= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs780077958, COSV52866013; called by mutect2, varscan2
- BVES | c.480T>G p.T160= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV58947014; called by muse, mutect2, varscan2
- CREB3L3 | c.1080C>T p.S360= | Silent (SNP) | VAF 18/70 reads (26%) | called by muse, varscan2
- CYP21A2 | c.726G>C p.L242= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as COSV64492306; called by muse, mutect2, varscan2
- DBX2 | c.273A>G p.Q91= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV60336738; called by muse, mutect2, varscan2
- DEDD2 | c.54G>A p.L18= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs763393943; called by muse, mutect2, varscan2
- ECHDC2 | c.606C>T p.H202= (on ENST00000371522 / NM_001198961.2; = p.H171= on NM_018281.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs200285963; called by muse, mutect2, varscan2
- EXOC2 | c.693G>A p.T231= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as rs1309683543, COSV100033407; called by muse, mutect2, varscan2
- EYA4 | c.1761A>G p.K587= (on ENST00000531901 / NM_001301013.1; = p.K581= on NM_004100.5) | Silent (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- FBXO31 | c.1275C>T p.G425= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs144062312; called by muse, mutect2, varscan2
- GJA5 | c.510C>A p.G170= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- GP5 | c.123G>A p.A41= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1043497790, COSV55462910; called by muse, mutect2
- GRIK3 | c.2673C>T p.V891= | Silent (SNP) | VAF 32/52 reads (62%) | called by muse, mutect2, varscan2
- GRM7 | c.252C>T p.Y84= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs747267079; called by muse, mutect2, varscan2
- KCNA3 | c.642C>T p.R214= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs1269316794, COSV63901113; called by muse, mutect2, varscan2
- KRT9 | c.594G>A p.Q198= | Silent (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2
- LTBR | c.996G>A p.Q332= | Silent (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- NKPD1 | c.2295G>A p.P765= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- OR10J1 | c.378C>A p.I126= | Silent (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- OR2A14 | c.72T>C p.I24= | Silent (SNP) | VAF 24/116 reads (21%) | called by muse, mutect2, varscan2
- P2RX5 | c.708C>T p.S236= | Silent (SNP) | VAF 37/64 reads (58%) | catalogued as rs1450261545, COSV56593343; called by muse, mutect2, varscan2
- PNLIPRP1 | c.366C>T p.C122= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as rs782174356, COSV62611160; called by muse, mutect2
- PPFIA4 | c.3147C>T p.Y1049= (on ENST00000447715; = p.Y1050= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs369972618; called by muse, mutect2, varscan2
- TEK | c.1308C>T p.P436= | Silent (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- TRPM6 | c.3840T>G p.S1280= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- TTN | c.102852C>G p.T34284= (on ENST00000591111; = p.T26860= on NM_003319.4) | Silent (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.85467A>G p.E28489= (on ENST00000591111; = p.E21065= on NM_003319.4) | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- ZNF829 | c.1044T>G p.G348= | Silent (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- TDP1 | c.1644+3652G>A | Intron (SNP) | VAF 4/30 reads (13%) | catalogued as rs776544229; called by mutect2, varscan2
